Surgical pathology report (de-identified scan), TCGA case TCGA-14-0812, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0812-01B (Primary Tumor).

[page 1 of 4]
AP Report

* Final Report *

TCGA-14-0812

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info:

* Final Report *

Anatomic Pathology Report

Patient:

Accession Number:

Patient Number:

Date Collected:

Financial Number:

Date Received:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT FRONTAL, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME.
2. BRAIN, LEFT FRONTAL, EXCISION, FS2A:
- GLIOBLASTOMA MULTIFORME.
3. BRAIN, LEFT FRONTAL, EXCISION:
- GLIOBLASTOMA MULTIFORME.

(Electronic Signature)

SPECIMEN:

1. Left frontal brain lesion
2. Left frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

PREVIOUS OPERATION OR BIOPSY: Not provided.

NAME OF OPERATION: Left frontal craniotomy for tumor excision.

Printed by:

Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
[REDACTED]

AP Report

[REDACTED]

* Final Report *

[REDACTED] TCGA-14-0812

PREOPERATIVE DIAGNOSIS: Brain tumor.

POSTOPERATIVE DIAGNOSIS: Not provided.

[REDACTED]

GROSS DESCRIPTION:

Received are two specimens, both are labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation and labeled "left frontal brain lesion". The specimen consists of tan-white, soft tissue measuring 0.8 x 0.4 x 0.4 cm. A touch preparation is made. A portion of the tissue is frozen and the remainder of that cryoblock is submitted in cassette "FS1A". The remaining tissue is submitted in cassette "1B".

Specimen #2 is received fresh for intraoperative consultation and labeled "left frontal brain lesion". The specimen consists of multiple fragments of tan-white, soft tissue measuring 0.5 x 0.5 x 0.3 cm. A touch preparation is made, a portion of the tissue is frozen and the remainder of that cryoblock is submitted in cassette "FS2A". The remaining tissue is submitted in cassette "2B".

Specimen #3 is received in formalin labeled with the patient's name and as "left frontal tumor". The specimen consists of cortex with overlying leptomeninges which are focally congested and measures 2.5 x 2.5 x 1.5 cm. Sectioning reveals tan-white tissue. Representative sections are submitted in cassettes "3A" and "3B".

[REDACTED]

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: LEFT FRONTAL BRAIN LESION (FROZEN SECTION, TOUCH PREPARATION):
GLIOBLASTOMA MULTIFORME.

FS2A, TP2A: LEFT FRONTAL BRAIN LESION (FROZEN SECTION, TOUCH PREPARATION):
GLIOBLASTOMA MULTIFORME.

Pathologist:

Page 1 (Continued...)

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
[REDACTED]

AP Report

* Final Report *

[REDACTED]

TCGA-14-0812

Patient: [REDACTED]
Patient Number: [REDACTED]

Accession Number: [REDACTED]

SURGICAL PATHOLOGY REPORT

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Resident: _

Fellow: _

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.9

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 3 of 4
(Continued)

[page 4 of 4]
AP Report

* Final Report *

TCGA-14-0812

Medical Records

Page 2 (End of Report)

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file 061f780a-d755-4de3-88de-a59831086af7 (TCGA-14-0812.182DF08C-7FA1-4C64-93F7-8C14A95349D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).